CPTAC case C3L-02957 — Bronchus and lung — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1562ff6a-080c-4b58-ba3a-9fdf50a5eaf6

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1961; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Upper lobe, lung; Age at diagnosis: 56.8 years (20,750 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC pathologic T: T2b; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Residual disease: R0; Days to last known disease status: 57 days; Days to last follow up: 57 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4.5 cm (a second GDC size field records 2.1 cm); Lymph node involvement: Positive; Lymph nodes positive: 2; Lymph nodes tested: 20; Margin status: Uninvolved.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 57.

Other clinical attributes
- Weight: 99.34 kg; Height: 162.56 cm; BMI: 37.59; DLCO (% of predicted): 81; FEV1/FVC after bronchodilator (%): 96; FEV1/FVC before bronchodilator (%): 79; FEV1 after bronchodilator (% of reference): 67; FEV1 before bronchodilator (% of reference): 60.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 18; Cigarettes per day: 10; Tobacco smoking onset year: 1981; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 41.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02957-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 964 mg; Time between excision and freezing: 27 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02957-22: Section location: Left Upper Lobe; Percent tumor nuclei: 70; Percent necrosis: 5.
- Sample C3L-02957-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 870 mg; Time between excision and freezing: 27 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02957-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
